TCGA case TCGA-SI-AA8C — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nerve Sheath Tumors; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Washington University St. Louis. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9b781072-66d8-49f2-80f7-7b020746b6e9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 20 years; Vital status: Alive.

Diagnoses (2)
1. Malignant peripheral nerve sheath tumor (the primary disease): ICD-O-3 morphology code: 9540/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 20.6 years (7,530 days); Year of diagnosis: 2013; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Sites of involvement: Lung, NOS; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 9.5; Tumor length measurement: 10.6; Tumor width measurement: 8.7.
   Pathology details: Measurement type: Pathologic; Tumor burden: 7.5.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 7; Tumor length measurement: 7.5; Tumor width measurement: 7.
   Pathology details: Measurement type: Radiologic; Tumor burden: 10.6.
2. Metastasis of diagnosis 1 (Malignant peripheral nerve sheath tumor), site: Lung, NOS. Age at diagnosis: 21.4 years (7,803 days); Days to diagnosis: 273 days; Prior treatment: Yes.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 1; Tumor width measurement: 0.6.

Follow-up (3 entries)
- Day 273 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 273 days.
- Days to follow up: 302 days; Disease response: With Tumor.
- Days to follow up: 597 days (1.6 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-SI-AA8C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 650 mg.
  Slide TCGA-SI-AA8C-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-SI-AA8C-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-SI-AA8C-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Malignant Peripheral Nerve Sheath Tumors (MPNST); Margin status: Positive; Tumor total necrosis: Extensive Necrosis (>50%); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: Yes; Metastasis site: Lung.
- Primary pathology, Synovial sarcoma: Mpnst nf indicator: NF1; Mpnst nf familial or sporadic: Sporadic; Mpnst nf1 genetic testing indicator: Yes, Mutations Identified; Mpnst nf1 mutations identified: Heterozygous truncating mutation,.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Thigh/knee.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic width: 7; Lesion pathologic depth: 7.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease.
- Radiation treatment: Days from index date to radiation therapy started: 42; Days from index date to radiation therapy ended: 93; Radiation therapy type: External; Radiation total dose: 66.6; Radiation adjuvant units: Gy; Radiation adjuvant fractions total: 37; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Complete Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 597 days; disease-specific survival: no event (censored), 597 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 273 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-SI-AA8C-01A-11D-A386-01): tumor purity 0.87, ploidy 1.84, whole-genome doublings 0.
